TCGA case TCGA-RD-A7BS — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Peter MacCallum Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa3d2d17-19e3-4b76-8235-98550f49dc91

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 46 years; Vital status: Dead; Days to death: 336 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Carcinoma, diffuse type (the primary disease): ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 46.1 years (16,847 days); Year of diagnosis: 2001; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 8.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 74 days; Days to treatment end: 104 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 102 days; Days to treatment end: 104 days; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
2. Metastasis of diagnosis 1 (Carcinoma, diffuse type), site: Liver. Age at diagnosis: 46.8 years (17,091 days); Days to diagnosis: 244 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 244 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 244 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 336 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus; Reflux treatment type: Proton Pump Inhibitors; Risk factors: Barrett's Esophagus.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RD-A7BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 110 mg.
  Slide TCGA-RD-A7BS-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RD-A7BS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RD-A7BS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; Cause of death: Stomach Cancer; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Gastroesophageal Junction; Lymph nodes examined: Yes; Tumor sample procurement country: Victoria; Cancer procurement city: Melbourne; History reflux disease indicator: No; Antireflux treatment: Yes; History barretts esophageal indicator: Yes; History hpylori infection indicator: No; Number of relatives with stomach cancer: 0; Treatment outcome first course: Complete Remission/Response.
- Drug treatment: Pharmaceutical therapy drug name: 5-FU.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 336 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 336 days; disease-free interval: event (new tumor event after initially disease-free), 244 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 244 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RD-A7BS-01A-11D-A32M-01): tumor purity 0.41, ploidy 1.89, whole-genome doublings 0.
